Surgical pathology report (de-identified scan), TCGA case TCGA-39-5019, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5019-01A (Primary Tumor).

[page 1 of 5]
TCGA-39-5019

Diagnosis & History:
with hamartoma of lung.

Specimens Submitted:

- 1: SP: Right upper lobe lung tru-cut biopsy
- 2: SP: Right level ten lymph node
- 3: SP: Right upper lobe lung
- 4: SP: Right anterior hilar lymph node
- 5: SP: Right level ten lymph node
- 6: SP: Level seven lymph node
- 7: SP: Right level four lymph node

DIAGNOSIS:

- 1) LUNG, RIGHT UPPER LOBE; TRU-CUT BIOPSY:
- NON-SMALL CELL CARCINOMA, FAVOR SQUAMOUS CELL CARCINOMA.
- 2) LYMPH NODE, LEVEL X, RIGHT; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LUNG, RIGHT UPPER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA OF THE RIGHT UPPER LOBE, MODERATELY TO POORLY DIFFERENTIATED.
- THE TUMOR'S GREATEST DIAMETER IS >3 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC LUNG SHOWS EMPHYSEMATOUS CHANGES AND FIBROSIS.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):
PERIBRONCHIAL - FOUR BENIGN LYMPH
NODES (0/4).
- 4) LYMPH NODES, HILUM, RIGHT ANTERIOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODES, LEVEL X, RIGHT; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

** Continued on next page **

[page 2 of 5]
- 6) LYMPH NODES, LEVEL VII; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODE, LEVEL IV, RIGHT; EXCISION:
- FRAGMENTS OF BENIGN LYMPH NODES

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh in the frozen section consultation labeled, "Right upper lobe lung tru-cut biopsy" and consists of three cores of gray-yellow soft tissue measuring 0.1 cm in diameter and ranging in size from 1.1 to 0.9 cm in length. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

2). The specimen is received fresh for frozen section consultation labeled, "Right level 10 lymph node" and consists of a fragment of tan-brown soft tissue measuring 1.1 x 0.8 x 0.3 cm which is entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

3) The specimen is received fresh for frozen section, labeled "Right upper lobe lung. Freeze bronchial margin". It consists of a 17 x 14 x 4.5 cm lobectomy specimen. There is a 4 cm diameter palpable tumor with a puckered pleural surface and a 0.6 x 0.2 cm eroded pleural surface identified. Cut section reveals the tumor to be a pigmented, white-tan, partially hemorrhagic mass, measuring 3.5 x 2.5 x 2.0 cm. The tumor is 2.5 cm from the main bronchial margin. 9.0 cm away from the tumor, there is a 1.5 x 1.0 x 0.6 cm bleb identified. The remainder of the lung is congested. Tissue is given for TPS. The bronchial margin is submitted for frozen. Representative sections submitted.

Summary of Sections:

** Continued on next page **

[page 3 of 5]
PSC - Frozen section control
T - Tumor
VM - Vascular margin
BL - Bleb
S - Sample
LN - Peribronchial lymph node

4) The specimen is received in formalin, labeled "Right anterior hilar lymph node". It consists of two lymph nodes, measuring 1.3 x 0.9 x 0.4 cm in aggregate. Entirely submitted.

Summary of Sections:
LN - Lymph node

5) The specimen is received in formalin, labeled "Right level 10 lymph node". It consists of two lymph nodes, measuring 1.5 x 0.6 x 0.5 cm in aggregate. Entirely submitted.

Summary of Sections:
LN - Lymph nodes

6) The specimen is received in formalin, labeled "Level 7 lymph node". It consists of a 2.0 x 1.2 x 0.5 cm fatty tissue containing three lymph nodes. Entirely submitted.

Summary of Sections:
LN - Lymph node

7) The specimen is received in formalin, labeled "Right level 4 lymph node". It consists of a 2.0 x 1.5 x 0.6 cm portion of fatty tissue. One possible lymph node is identified. Entirely submitted.

Summary of Sections:
LN - Lymph node

Summary of Sections:

** Continued on next page **

[page 4 of 5]
Part 1: SP: Right upper lobe lung trucut biopsy () ()

Block	Sect.	Site	PCs
1		PSC	3

Part 2: SP: Right level ten lymph node () ()

Block	Sect.	Site	PCs
1		PSC	1

Part 3: SP: Right upper lobe lung () ()

Block	Sect.	Site	PCs
1		EL	1
1		PSC	1
1		LN	2
4		S	4
3		T	3
1		VM	2

Part 4: SP: Right anterior hilar lymph node ()

Block	Sect.	Site	PCs
1		LN	2

Part 5: SP: Right level ten lymph node ()

Block	Sect.	Site	PCs
1		LN	2

Part 6: SP: Level seven lymph node ()

Block	Sect.	Site	PCs
1		LN	1

Part 7: SP: Right level four lymph node ()

Block	Sect.	Site	PCs
1		LN	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: NON-SMALL CELL CARCINOMA, FAVOR SQUAMOUS CELL. ()

PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: BENIGN. ()

PERMANENT DIAGNOSIS: SAME.

** Continued on next page **

[page 5 of 5]
** End of Report **

Source: NCI Genomic Data Commons file 0673b45c-dd0d-49de-a75a-f5935439d71c (TCGA-39-5019.6CD83ACA-C74C-49A4-8115-324E7C359CC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).